Surgical pathology report (de-identified scan), TCGA case TCGA-ZM-AA06, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Ulm, specimen TCGA-ZM-AA06-01A (Primary Tumor).

ICD O-3
Seminoma NOS 9061/3
Site R Testis NOS C629
JW 3/13/14

Date of procurement:

Pathohistological diagnosis

Seminoma testis (pT2 NXMX), right testicle

Description:

A testicle with tumor, size 7:5.5:4.5 cm with 9 cm long funiculus and 2.5-3 cm diameter was received. Inside the testicle we find white, nodular tumor tissue with hemorrhaging and necrotic areas encompassing an area of 6.2:5:4.5 cm. Histologically, the tumor is made of solid tumor cell clusters with round and oval bright nuclei with pronounced smaller nuclei with medium abundant bright cytoplasm. Around tumor cells we find lymphocyte seat clusters. Furthermore, we observed up to 5 mitosis per microscope large visual field. On several location we observed sinciotrophoblast cells. Surrounding, preserved, testicular tissue is mostly atrophic.

The tumor infiltrates tunica albuginea and vascular areas, but does not infiltrate rete testis, epididymis nor funiculus.

Source: NCI Genomic Data Commons file 748e4fae-fcf9-4956-9f82-48b671e3fc01 (TCGA-ZM-AA06.39C6A721-71D7-4B88-AE64-83FAD250E974.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).